Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A3PJ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A3PJ-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: URETER, LEFT DISTAL MARGIN, BIOPSY -
BENIGN UROTHELIUM UNDERLYING SUBMUCOSAL MUCOSA WITH REACTIVE CHANGES, NEGATIVE FOR TUMOR.

PART 2: URETER, RIGHT DISTAL MARGIN, BIOPSY -
BENIGN UROTHELIUM UNDERLYING SUBMUCOSAL MUCOSA WITH REACTIVE CHANGES, NEGATIVE FOR TUMOR.

PART 3: BLADDER AND PROSTATE -
FOR THE BLADDER:

- A. INVASIVE HIGH GRADE UROTHELIAL CARCINOMA.
- B. THE CARCINOMA MEASURES 3.5 CM IN GREATEST DIMENSION AND IS PRESENT UNDERLYING AN ULCERATED AREA.
- C. FLAT UROTHELIAL CARCINOMA IN SITU (CIS).
- D. THE CARCINOMA INVOLVES THE LEFT LATERAL WALL.
- E. THE CARCINOMA INVADES THROUGH THE DETRUSOR MUSCLE TO INVOLVE THE PERIVESICULAR SOFT TISSUE.
- F. LYMPHOVASCULAR AND PERINEURAL INVASION IS NOT IDENTIFIED.
- G. EXTENSIVE THERAPY-RELATED CHANGES.
- H. ALL SURGICAL MARGINS ARE NEGATIVE.
- I. PATHOLOGICAL STAGE: pT3a NO MX.

PROSTATE:

- A. PROSTATIC ADENOCARCINOMA, GLEASON SCORE: 3+4=7
- B. CARCINOMA INVOLVES 5% OF THE TISSUE FROM THE RIGHT LOBE.
- C. PATHOLOGICAL STAGE: pT2a NO MX.
- D. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN).

PART 4: LYMPH NODES, RIGHT PELVIC, EXCISION -
NINETEEN (19) BENIGN LYMPH NODES, NEGATIVE FOR TUMOR.

PART 5: LYMPH NODES, LEFT PELVIC, EXCISION -
NINE (9) BENIGN LYMPH NODES WITH REACTIVE CHANGES, NEGATIVE FOR TUMOR.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystoprostatectomy
TUMOR SITE: Left lateral wall
TUMOR SIZE: Greatest dimension: 3.5 cm
HISTOLOGIC TYPE: Urothelial (transitional cell) carcinoma
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Papillary, Solid/nodule
PATHOLOGIC STAGING (pTNM): pT3b
pN0
Number of nodes examined: 28
Number of nodes involved: 0
pMX
Margins uninvolved by invasive carcinoma

MARGINS:

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Absent

DIRECT EXTENSION OF INVASIVE TUMOR: Perivesical fat

ADDITIONAL PATHOLOGIC FINDINGS: Urothelial carcinoma in situ
Therapy-related changes

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 20%
WEIGHT OF PROSTATE: 33.39gm
TUMOR SIZE: Maximum dimension: 1.2 cm
LOBE LATERALITY: Right Lobe
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: No
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 28
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2a
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

ICD-0-3
carcinoma, urothelial
8120/3
Site: bladder, wall, lateral
C67.2
TSS confirmed,
No prior systemic tx.
LW

Source: NCI Genomic Data Commons file b97f7eea-970b-4052-aa27-a359fad18539 (TCGA-BT-A3PJ.D2E98BC0-ED05-4653-9515-259D0361F2C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).